ALCHEMIST case ALCH-B3ZZ — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/46dd65a4-193f-4547-b132-2963c796dd8c

Demographics
Sex at birth: male.

Diagnoses (1)
1. Carcinoma, NOS: Age at diagnosis: 67.7 years (24,725 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B3ZZ-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B3ZZ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B3ZZ-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 38; Percent tumor nuclei: 67; Percent normal cells: 48; Percent necrosis: 0; Percent stromal cells: 14; Percent lymphocyte infiltration: 26; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
